Somatic mutation profile of tumor specimen C3N-03021-01 (aliquot CPT0189110006) from CPTAC case C3N-03021, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 50.6 years (18,491 days).
Specimen C3N-03021-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72b579d8-d69c-454b-8468-fd78005598d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03021-31 (Blood Derived Normal), aliquot CPT0189150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7242e926-4e57-41b4-a34f-1af1177147d7

The open-access MAF lists 60 somatic variants for this specimen: 47 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 6, Frame Shift Del 4, Intron 3, Nonsense Mutation 3, 3'UTR 3, In Frame Del 2, Frame Shift Ins 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMK2D | c.1291T>C p.Y431H | Missense Mutation (SNP) | VAF 120/471 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV56436000; called by muse, mutect2, varscan2
- CHRD | c.239G>A p.C80Y | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759391287; called by muse, mutect2, varscan2
- EMILIN2 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.021); catalogued as rs759998658; called by muse, varscan2
- HIPK4 | c.1195_1197del p.K399del | In Frame Del (DEL) | VAF 49/211 reads (23%) | catalogued as rs1409868158; called by mutect2, pindel, varscan2
- LYZL6 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 92/288 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs768033779; called by muse, mutect2, varscan2
- MYLK4 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.418); catalogued as rs766618649; called by muse, mutect2, varscan2
- NKIRAS1 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 93/299 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as rs913233973; called by muse, mutect2, varscan2
- PCDH1 | c.2908C>T p.R970C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1322349520; called by muse, mutect2, varscan2
- SBDS | c.18del p.T7Pfs*6 | Frame Shift Del (DEL) | VAF 127/510 reads (25%) | catalogued as CD146376; called by mutect2, pindel, varscan2
- TAF8 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV65896803; called by muse, mutect2, varscan2
- ZNF804A | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 45/165 reads (27%) | catalogued as COSV56467533; called by muse, mutect2, varscan2
- ACOX1 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 122/720 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); called by muse, mutect2
- AKAP4 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 85/139 reads (61%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ALG2 | c.139G>C p.V47L | Missense Mutation (SNP) | VAF 147/582 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BICDL1 | c.435dup p.E146Rfs*6 | Frame Shift Ins (INS) | VAF 25/99 reads (25%) | called by mutect2, pindel, varscan2
- BLZF1 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BTN2A2 | c.884T>A p.I295N | Missense Mutation (SNP) | VAF 93/301 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CCDC136 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 71/293 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- CETP | c.344A>G p.K115R | Missense Mutation (SNP) | VAF 474/1027 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CLDN25 | c.367_370del p.R123Lfs*75 | Frame Shift Del (DEL) | VAF 67/252 reads (27%) | called by mutect2, pindel, varscan2
- COL9A1 | c.1672C>G p.P558A | Missense Mutation (SNP) | VAF 155/490 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CTDP1 | c.426_440delinsT p.Q142Hfs*21 | Frame Shift Del (DEL) | VAF 84/587 reads (14%) | called by pindel, varscan2*
- CUL3 | c.2190G>T p.L730F | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DGKD | c.2710A>C p.I904L (on ENST00000264057 / NM_152879.3; = p.I860L on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/279 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DHX36 | c.1573C>T p.H525Y | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DHX9 | c.2181_2192del p.V728_S731del | In Frame Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, varscan2
- ESYT3 | c.1315G>T p.G439C | Missense Mutation (SNP) | VAF 93/303 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- EVC2 | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 205/754 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- GMCL2 | c.1055A>T p.D352V | Missense Mutation (SNP) | VAF 99/330 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GXYLT1 | c.249G>T p.W83C | Missense Mutation (SNP) | VAF 95/315 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HTR4 | c.1040C>G p.S347* | Nonsense Mutation (SNP) | VAF 48/140 reads (34%) | called by muse, mutect2, varscan2
- ITGAX | c.3478C>T p.P1160S | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LSM14A | c.28A>C p.S10R | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- MOSPD2 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 106/186 reads (57%) | SIFT tolerated (0.46); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MS4A4E | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYBPC3 | c.2855C>G p.P952R | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NELL1 | c.1176dup p.N393* | Frame Shift Ins (INS) | VAF 27/121 reads (22%) | called by mutect2, pindel
- NEUROD6 | c.141C>A p.S47R | Missense Mutation (SNP) | VAF 114/502 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NEUROD6 | c.140G>C p.S47T | Missense Mutation (SNP) | VAF 112/502 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRDM8 | c.919A>T p.T307S | Missense Mutation (SNP) | VAF 27/309 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- SEC31B | c.79G>T p.G27* | Nonsense Mutation (SNP) | VAF 110/333 reads (33%) | called by muse, mutect2, varscan2
- SLC6A4 | c.1216C>G p.L406V | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- STAG2 | c.2289del p.K763Nfs*3 | Frame Shift Del (DEL) | VAF 29/73 reads (40%) | called by mutect2, pindel, varscan2
- STIM1 | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 195/597 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- USP34 | c.1159-1G>T p.X387_splice | Splice Site (SNP) | VAF 73/286 reads (26%) | called by muse, mutect2, varscan2
- ZBTB1 | c.360T>G p.D120E | Missense Mutation (SNP) | VAF 81/259 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ZNF550 | c.214A>G p.I72V | Missense Mutation (SNP) | VAF 81/286 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM22 | c.2364T>A p.I788= | Silent (SNP) | VAF 65/198 reads (33%) | called by muse, mutect2, varscan2
- CWF19L1 | c.78A>G p.Q26= | Silent (SNP) | VAF 28/110 reads (25%) | called by muse, mutect2, varscan2
- DCAF16 | c.594T>G p.T198= | Silent (SNP) | VAF 74/203 reads (36%) | catalogued as COSV66384205; called by muse, mutect2, varscan2
- THAP11 | c.111C>T p.L37= | Silent (SNP) | VAF 92/477 reads (19%) | called by muse, mutect2, varscan2
- TP63 | c.300C>T p.D100= | Silent (SNP) | VAF 133/454 reads (29%) | called by muse, mutect2, varscan2
- ZNF227 | c.1140C>T p.Y380= | Silent (SNP) | VAF 78/230 reads (34%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.4726+54C>A | Intron (SNP) | VAF 87/340 reads (26%) | called by muse, mutect2, varscan2
- DVL3 | c.*170G>C | 3'UTR (SNP) | VAF 49/210 reads (23%) | catalogued as rs746446875; called by muse, mutect2, varscan2
- FMNL1 | c.3212-43T>A | Intron (SNP) | VAF 54/199 reads (27%) | called by muse, mutect2, varscan2
- FUS | c.-42T>A | 5'UTR (SNP) | VAF 352/781 reads (45%) | catalogued as rs367552345; called by muse, mutect2, varscan2
- PDE6B | c.*101A>G | 3'UTR (SNP) | VAF 83/292 reads (28%) | called by muse, mutect2, varscan2
- RPA2 | c.10+19G>T | Intron (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- TMEM135 | c.*1937A>G | 3'UTR (SNP) | VAF 48/210 reads (23%) | called by muse, mutect2, varscan2
